Somatic mutation profile of tumor specimen TCGA-23-1113-01A (aliquot TCGA-23-1113-01A-01W-0486-08) from TCGA case TCGA-23-1113, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 48.7 years (17,791 days).
Specimen TCGA-23-1113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 761f828f-4476-4fd4-b53c-d747a5c7524b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1113-10A (Blood Derived Normal), aliquot TCGA-23-1113-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b74cb640-5323-4ee3-a3a0-649ac742762f

The open-access MAF lists 46 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>C p.X187_splice | Splice Site (SNP) | VAF 257/307 reads (84%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AMER1 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 797/1771 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs372775016, COSV100366060; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP28 | c.1939G>A p.A647T (on ENST00000383472 / NM_001366230.1; = p.A488T on NM_001010000.3) | Missense Mutation (SNP) | VAF 140/186 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1203525791, COSV51632031; called by muse, mutect2, varscan2
- ATP8A2 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 508/1232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764092726, COSV99681846; called by muse, mutect2, varscan2
- CAPRIN2 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99195498; called by muse, mutect2, varscan2
- CREBBP | c.3061-2A>G p.X1021_splice | Splice Site (SNP) | VAF 149/233 reads (64%) | catalogued as COSV52116988; called by muse, mutect2, varscan2
- CXorf66 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 444/1039 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV100983879; called by muse, mutect2, varscan2
- DMD | c.406A>G p.S136G | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV99922245; called by muse, mutect2, varscan2
- DOCK11 | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52247544, COSV99353751; called by muse, mutect2, varscan2
- EPHB6 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0.236); catalogued as COSV100844282; called by muse, mutect2, varscan2
- FAM47C | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs782156241, COSV100792524; called by muse, mutect2, varscan2
- GARNL3 | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 776/1710 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.699); catalogued as rs1241642760, COSV100150232; called by muse, mutect2, varscan2
- GRIK3 | c.1616G>A p.G539D | Missense Mutation (SNP) | VAF 177/514 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100902002; called by muse, mutect2, varscan2
- HECW1 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 261/552 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101223477, COSV67826792; called by muse, mutect2, varscan2
- HMCN1 | c.8946C>G p.I2982M | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54924002; called by muse, mutect2, varscan2
- HSPG2 | c.11423C>T p.P3808L | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV101013461; called by muse, mutect2, varscan2
- JAK3 | c.2054C>A p.T685N | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV101512927; called by muse, mutect2, varscan2
- KLHL6 | c.1323C>A p.Y441* | Nonsense Mutation (SNP) | VAF 176/418 reads (42%) | catalogued as COSV100384621, COSV58067408; called by muse, mutect2, varscan2
- MCF2 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 102/277 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1425786540, COSV100644764, COSV100645034; called by muse, mutect2, varscan2
- OR2T27 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100788235, COSV61281316; called by muse, mutect2, varscan2
- PHF24 | c.884G>C p.R295P | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99646063; called by muse, mutect2, varscan2
- PIK3C2G | c.2545T>C p.W849R (on ENST00000676171; = p.W808R on NM_004570.5) | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs374310738; called by muse, mutect2, varscan2
- PPP1R3D | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs778759736, COSV100674516; called by muse, mutect2, varscan2
- PWWP3B | c.1583T>A p.V528E | Missense Mutation (SNP) | VAF 188/456 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.368); catalogued as COSV100531226; called by muse, mutect2, varscan2
- RAE1 | c.805G>C p.A269P | Missense Mutation (SNP) | VAF 248/570 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs750041396, COSV100982422; called by muse, mutect2, varscan2
- SENP1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 154/367 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs760013799, COSV99136927; called by muse, mutect2, varscan2
- SLC22A5 | c.1571T>A p.M524K | Missense Mutation (SNP) | VAF 295/344 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV99809916; called by muse, mutect2, varscan2
- SNAPC3 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV101072755; called by muse, mutect2, varscan2
- SPTA1 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 262/550 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs147573740, COSV100934898; called by muse, mutect2, varscan2
- TM7SF2 | c.1028G>A p.W343* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99659647; called by mutect2, varscan2
- TMEM168 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.34); catalogued as rs559732706, COSV57179723; called by muse, mutect2, varscan2
- ZNF133 | c.1176G>T p.R392S (on ENST00000316358 / NM_001352454.2; = p.R391S on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/1440 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV100315487; called by muse, mutect2
- ZNF347 | c.895A>T p.R299* | Nonsense Mutation (SNP) | VAF 48/1164 reads (4%) | catalogued as rs148409173, COSV100498277; called by muse, mutect2
- ZNF510 | c.1444C>G p.H482D | Missense Mutation (SNP) | VAF 144/311 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99793847; called by muse, mutect2, varscan2
- HDAC6 | c.45_47del p.R15del | In Frame Del (DEL) | VAF 30/69 reads (43%) | called by pindel, varscan2
- PUM1 | c.1969_1970del p.S657Qfs*21 | Frame Shift Del (DEL) | VAF 137/390 reads (35%) | called by pindel, varscan2
- TLN2 | c.158_161del p.L53Rfs*46 | Frame Shift Del (DEL) | VAF 86/108 reads (80%) | called by pindel, varscan2
- ALG13 | c.2944T>C p.L982= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs759545615, COSV99322178; called by muse, mutect2, varscan2
- DGKK | c.1455A>T p.S485= | Silent (SNP) | VAF 373/785 reads (48%) | catalogued as COSV101052988; called by muse, mutect2, varscan2
- GPR65 | c.825G>A p.T275= | Silent (SNP) | VAF 163/384 reads (42%) | catalogued as rs1428008497, COSV99966032; called by muse, mutect2, varscan2
- MTUS2 | c.1314T>G p.A438= | Silent (SNP) | VAF 478/1146 reads (42%) | catalogued as rs1387908159, COSV101462200; called by mutect2, varscan2
- NCOR2 | c.2568G>A p.G856= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV100657303; called by muse, mutect2, varscan2
- NUDT18 | c.660C>A p.G220= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99248973; called by muse, mutect2, varscan2
- SLC41A3 | c.1377C>T p.S459= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs772901628, COSV59991216; called by muse, mutect2, varscan2
- ZSCAN22 | c.1089C>G p.R363= | Silent (SNP) | VAF 44/200 reads (22%) | called by muse, varscan2
- RRM2 | n.393C>T | RNA (SNP) | VAF 330/733 reads (45%) | called by muse, mutect2, varscan2
